CCDI case PBCPVC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/71af9454-8e33-4352-94ff-34a0b68bb931

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 14.9 years (5,439 days).

Biospecimens (3 samples)
- Sample 0DX4ET: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX4F7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DX4FP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
